Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8080, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8080-01A (Primary Tumor).

[page 1 of 2]
					STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 20 x 12 x 2.5 cm Tumor features: None specified Histologic type: Mucinous adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Greater and lesser omentum Lymph nodes: 10/12 positive for metastasis (Intraabdominal 10/12) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None
--	--	--	--	--	---

[page 2 of 2]
Fundus		
--------	--	--

Source: NCI Genomic Data Commons file 7bdf1676-b400-4ec5-901d-c4636bec324e (TCGA-BR-8080.1DA8CDB2-8900-481D-8303-69562E2628C1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).